TCGA case TCGA-HS-A5NA — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: Ontario Institute for Cancer Research (OICR). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0020317d-d10e-4e75-8fa6-7c1bdcdee471

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 65 years; Vital status: Alive.

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 65.8 years (24,025 days); Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Sites of involvement: Ovary, Left / Ovary, Right / Uterus; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 16.5; Tumor length measurement: 26; Tumor width measurement: 21.
   Pathology details: Measurement type: Pathologic; Tumor burden: 26.
   Pathology details: Consistent pathology review: Yes; Necrosis present: No; Tumor depth descriptor: Deep.
2. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS). Prior treatment: Yes.

Follow-up (2 entries)
- Days to follow up: 298 days; Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 20.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HS-A5NA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 400 mg.
  Slide TCGA-HS-A5NA-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HS-A5NA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HS-A5NA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Metastatic disease confirmed: No; Contiguous organ resection: bilateral ovaries; Contiguous organ invaded: Yes.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Radiation treatment: Days from index date to radiation therapy ended: 153; Radiation therapy type: External; Radiation total dose: 63; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 27; Radiation therapy site: Regional site; Radiation therapy ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 298 days; disease-specific survival: no event (censored), 298 days; progression-free interval: no event (censored), 298 days.
